Gene-level copy-number profile of tumor specimen ALCH-AEOU-TTP1-A from ALCHEMIST case ALCH-AEOU, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 46.6 years (17,008 days).
Specimen ALCH-AEOU-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 48a3609b-65ac-49be-babb-6e8fbb57d9eb.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AEOU-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,716 have no estimate.
https://portal.gdc.cancer.gov/files/6ecf452c-5dc4-41c9-bfc7-e8646f11eb89

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 555; copy number 1: 409; copy number 2: 15,506; copy number 3: 14,743; copy number 4: 19,342; copy number 5: 4,930; copy number 6: 1,587; copy number 7: 1,047; copy number 8: 103; copy number 9: 429; copy number 10: 109; copy number 11: 88; copy number 12: 37; copy number 14: 8; copy number 16: 14.

Homozygous deletions (total copy number 0; autosomes only): 40 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:3,454,665–3,736,201, 10 genes (within-gene range 0–2): ARHGEF16, AL512413.1, MEGF6, MIR551A, AL513320.1, TPRG1L, WRAP73, TP73, TP73-AS3, TP73-AS2.
- chr2:241,776,822–241,817,413, 4 genes: GAL3ST2, AC131097.1, AC131097.2, NEU4.
- chr3:75,521,803–75,522,012, 1 gene: SNRPCP10.
- chr3:75,542,149–75,542,929, 1 gene (within-gene range 0–2): RPS3AP15.
- chr7:1,459,937–1,504,389, 3 genes: AC102953.1, AC102953.2, INTS1.
- chr8:7,170,550–7,170,741, 1 gene: SNRPCP15.
- chr9:42,011,350–42,499,134, 11 genes (within-gene range 0–2): RN7SL343P, SPATA31A6, AL445584.1, FAM74A7, AL445584.3, AL445584.2, FKBP4P6, SDR42E1P2, ATP5F1AP1, RAB28P3, RBPJP6.
- chr9:42,579,414–42,626,813, 2 genes: BX088651.2, FGF7P5.
- chr12:131,828,393–131,851,783, 1 gene: MMP17.
- chr16:1,770,286–1,794,971, 6 genes (within-gene range 0–4): NME3, MRPS34, EME2, SPSB3, NUBP2, IGFALS.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 685 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:117,953,590–121,580,524, 82 genes, copy number 10–16 (within-gene range 2–16) (broad region; genes not listed).
- chr3:144,186,905–149,291,800, 55 genes, copy number 9–12 (within-gene range 7–12): RNA5SP144, AC011592.1, LARP7P4, GM2AP1, RPL21P39, AC055758.2, AC055758.1, AC107021.2, AC107021.1, LNCSRLR, PLOD2, PLSCR4, AC130509.1, AC069528.1, PLSCR2, AC069528.2, PLSCR1, RNU6-428P, PLSCR5, PLSCR5-AS1, AC092957.1, LINC02010, RNU6-505P, RPL21P71, ZIC4, ZIC4-AS1, ZIC1, NPM1P28, AC092925.1, AC092958.1, AC092958.4, LINC02032, AC092958.3, AC092958.2, AC025566.1, HNRNPA1P20, LINC02045, LINC02046, AC069410.1, RPL38P1, AGTR1, CPB1, HMGB1P30, AC092979.1, CPA3, AC092979.2, UBQLN4P1, GYG1, HLTF, HLTF-AS1, Y_RNA, MED28P2, HPS3, CP, CPHL1P.
- chr3:150,541,998–153,200,017, 50 genes, copy number 9: SERP1, EIF2A, SELENOT, AC069236.1, ERICH6, ERICH6-AS1, SNRPCP3, SIAH2, SIAH2-AS1, CLRN1-AS1, MINDY4B, AC020636.2, AC020636.1, CLRN1, AC108726.1, MED12L, RNA5SP145, GPR171, P2RY14, SETP11, AC078816.1, GPR87, P2RY13, P2RY12, IGSF10, MRPL42P6, AC117454.1, MIR5186, LINC02066, AADACL2, AADACL2-AS1, AC068647.1, AADACP1, AC068647.2, AADAC, SUCNR1, AC108718.1, MBNL1, MBNL1-AS1, TMEM14EP, Y_RNA, AC026347.1, AC092924.1, ATP5MGP5, P2RY1, HMGN2P13, AC117394.1, AC117394.2, RAP2B, RN7SL300P.
- chr3:154,007,367–154,861,017, 14 genes, copy number 9: U8, RPL21P42, ARHGEF26-AS1, ARHGEF26, DHX36, AC134026.1, AC134026.2, GPR149, DDX50P2, AC092994.1, SYPL1P1, DYNLL1P5, RPL9P15, AC073359.2.
- chr3:157,814,822–158,088,997, 1 gene, copy number 9 (within-gene range 6–9): AC079943.2.
- chr3:158,095,905–158,871,821, 20 genes, copy number 9: SHOX2, RSRC1, AC074276.1, AC074276.2, AC106707.2, AC106707.1, MLF1, MTAPP1, AC025033.1, GFM1, LXN, AC080013.3, RARRES1, MFSD1, AC080013.1, RPL35AP9, AC080013.2, AC080013.4, GPR79, AC092999.1.
- chr3:161,816,909–167,408,519, 35 genes, copy number 10–11: AC131211.1, TOMM22P6, AC128716.1, AC128685.1, LINC01192, RPS6P4, AC079910.1, RNU7-82P, AC084017.1, MIR1263, LINC01323, LINC01324, SI, Y_RNA, LINC02023, SLITRK3, LINC01322, BCHE, MTND4P17, MTND4LP10, MTND3P7, MTCO3P38, MCUR1P2, AC104629.1, LINC01326, AC072046.2, RN7SKP298, PSAT1P4, AC072046.1, CBX1P5, AC069439.2, AC069439.1, PPIAP74, ZBBX, LINC01327.
- chr3:167,478,684–170,353,961, 54 genes, copy number 9–11 (within-gene range 5–11): WDR49, PDCD10, HMGN1P8, SERPINI1, AC079822.1, LRRC77P, AC026353.1, MEMO1P3, AC128713.1, HMGN2P26, GOLIM4, AC069243.1, EGFEM1P, AC124893.1, RNU2-20P, MIR551B, RPSAP33, RPL21P43, LINC02082, AC092954.1, AC092954.2, LINC01997, MECOM, MECOM-AS1, RPL22P1, AC007849.1, SDHDP3, RNU6-637P, TERC, Telomerase-vert, ACTRT3, AC078802.1, MYNN, AC078795.1, LRRC34, AC078795.3, AC078795.2, LRRIQ4, LRRC31, KRT18P43, SAMD7, AC008040.2, AC008040.1, AC008040.3, SEC62, SEC62-AS1, GPR160, RNU4-38P, KMT5AP3, PHC3, RNU6-315P, PRKCI, Y_RNA, AC073288.1.
- chr3:173,153,737–174,286,644, 5 genes, copy number 10: AC068759.1, NLGN1, AC092967.1, NLGN1-AS1, RN7SKP234.
- chr3:176,415,439–179,627,647, 49 genes, copy number 9–12 (within-gene range 7–12): LINC01208, RNA5SP147, LINC01209, MTND5P15, TBL1XR1, TBL1XR1-AS1, Y_RNA, RNU6-681P, LINC00501, ASS1P7, AC117465.1, LINC00578, RN7SKP52, AC026355.3, AC026355.1, AC026355.2, AC026355.4, LINC02015, AC007953.1, AC007953.2, RNU6-1120P, AC117453.1, KCNMB2, AC117457.1, LINC01014, RNA5SP148, PPIAP75, KCNMB2-AS1, ZMAT3, Y_RNA, AC076966.2, PIK3CA, AC076966.1, KCNMB3, LRRFIP1P1, ZNF639, AC007823.1, MFN1, GNB4, AC007620.2, AC007620.3, AC007620.1, MTHFD2P7, ACTL6A, AC090425.3, AC090425.2, MRPL47, NDUFB5, AC090425.1.
- chr3:180,542,701–185,281,990, 121 genes, copy number 9–11 (broad region; genes not listed).
- chr3:186,046,314–187,078,553, 40 genes, copy number 9: ETV5, Metazoa_SRP, ETV5-AS1, DGKG, LINC02020, LINC02052, LINC02051, CRYGS, TBCCD1, DNAJB11, AC068631.1, AC068631.2, AC068631.3, AHSG, Metazoa_SRP, FETUB, HRG, AC109780.1, AC109780.2, KNG1, PSMD10P2, RNU6-1105P, GPS2P2, AC112907.3, EIF4A2, SNORD2, SNORA63B, MIR1248, SNORA81, SNORA63, SNORA4, RFC4, AC112907.1, LINC02043, AC112907.2, ADIPOQ, ADIPOQ-AS1, RPS20P14, AC007690.1, ST6GAL1.
- chr3:190,322,541–192,767,764, 27 genes, copy number 10: CLDN16, TMEM207, IL1RAP, GCNT1P3, RN7SKP296, AC108747.1, LINC02013, CCT6P4, AC092952.1, GMNC, OSTN, OSTN-AS1, UTS2B, CCDC50, AC073365.1, PYDC2, Y_RNA, AC026320.2, AC026320.1, AC026320.3, RN7SKP222, FGF12, FGF12-AS1, FGF12-AS2, FGF12-AS3, AC026671.1, RNU1-20P.
- chr3:194,584,004–198,123,232, 131 genes, copy number 9 (broad region; genes not listed).
- chr21:44,133,610–44,210,114, 1 gene, copy number 9 (within-gene range 2–9): GATD3A.

Autosomal genes at a single copy (total copy number 1): 405. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
